TCGA case TCGA-HC-7741 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/231a45e7-ad33-4789-a9fc-74ce7a18fcc3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 67.4 years (24,608 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Tumor level prostate: Apex / Middle / Base.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Day 9 (initial diagnosis): Days to imaging: 9 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Days to follow up: 1,752 days (4.8 years); Disease response: Tumor Free.
- Days to follow up: 1,969 days (5.4 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 1,969 days (5.4 years).
- Days to follow up: 2,725 days (7.5 years); Disease response: Tumor Free.
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.1 ng/mL (day 146).

Biospecimens (2 samples)
- Sample TCGA-HC-7741-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample TCGA-HC-7741-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Days to bone scan: 9; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Days to ct scan ab pelvis: 9; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.1.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 4.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,725 days; disease-specific survival: no event (censored), 2,725 days; disease-free interval: no event (censored), 2,725 days; progression-free interval: no event (censored), 2,725 days.
